FM case AD3013 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/76c1ac58-7a8e-483b-a125-a32de289779c

Male, 65.4 years: diagnosis not reported by GDC; metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 50% (pathologist estimate recorded by GDC). Sample type: Metastatic.
